Somatic mutation profile of tumor specimen TCGA-43-6770-01A (aliquot TCGA-43-6770-01A-11D-1817-08) from TCGA case TCGA-43-6770, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.4 years (21,683 days).
Specimen TCGA-43-6770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88f1972e-eccf-4ee2-b421-c993de3b1618.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-6770-10A (Blood Derived Normal), aliquot TCGA-43-6770-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05ac116a-7818-4d21-9678-0cd691b2112e

The open-access MAF lists 237 somatic variants for this specimen: 183 protein-altering or splice-affecting, 48 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 48, Frame Shift Del 13, Nonsense Mutation 7, Splice Site 6, RNA 4, Splice Region 2, In Frame Del 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 35/62 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.1643T>C p.V548A (on ENST00000373394 / NM_001271696.3; = p.V549A on NM_004299.6) | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99504299; called by muse, mutect2, varscan2
- ACE2 | c.697-1G>A p.X233_splice | Splice Site (SNP) | VAF 7/83 reads (8%) | catalogued as COSV53025416, COSV53026658; called by muse, mutect2
- ACTL9 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV61006077; called by muse, mutect2, varscan2
- ADAM19 | c.903C>A p.I301= | Splice Region (SNP) | VAF 23/43 reads (53%) | catalogued as COSV57431421, COSV57441506; called by muse, mutect2, varscan2
- ADPRH | c.31A>C p.S11R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63695163; called by muse, mutect2, varscan2
- AK9 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99572496; called by muse, mutect2, varscan2
- ALPK2 | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64493808, COSV64494107; called by muse, mutect2, varscan2
- ANKRD35 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV62910620; called by mutect2, varscan2
- AP3B2 | c.2643C>A p.Y881* (on ENST00000261722; = p.Y875* on NM_004644.5) | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV55610324; called by muse, mutect2
- ARHGDIB | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56763611; called by muse, mutect2, varscan2
- ARL13A | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as rs749179565, COSV65880199; called by muse, mutect2
- ATAD2B | c.251A>T p.H84L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.343); catalogued as COSV53200422; called by muse, mutect2, varscan2
- ATG4D | c.979T>C p.C327R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1298672547, COSV57264857; called by muse, mutect2, varscan2
- ATG9B | c.752G>C p.R251T | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs768574601, COSV65058269; called by muse, mutect2, varscan2
- BIRC6 | c.7156C>G p.L2386V | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70200259; called by muse, mutect2, varscan2
- CCDC38 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60183407; called by muse, mutect2, varscan2
- CDH26 | c.646A>C p.S216R | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.162); catalogued as COSV54847999; called by muse, mutect2, varscan2
- CDHR2 | c.2143G>A p.V715M | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs773049926, COSV56140171; called by muse, mutect2, varscan2
- CEP131 | c.3009G>T p.E1003D (on ENST00000269392 / NM_001319228.2; = p.E1000D on NM_014984.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV53953610; called by muse, mutect2, varscan2
- CHRNB2 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63808461; called by muse, mutect2, varscan2
- COL7A1 | c.6190G>T p.G2064* | Nonsense Mutation (SNP) | VAF 43/105 reads (41%) | catalogued as CM980411, COSV60396432; called by muse, mutect2, varscan2
- CRABP2 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1392716041, COSV63958954; called by muse, mutect2, varscan2
- CTIF | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.095); catalogued as COSV56485410; called by muse, mutect2, varscan2
- CXorf65 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV52148757; called by muse, mutect2, varscan2
- CYLC2 | c.202del p.R68Efs*14 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | catalogued as COSV100872416; called by mutect2, pindel, varscan2
- DCAF17 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV59830460; called by muse, mutect2
- DLG2 | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV54652328; called by muse, mutect2, varscan2
- DMD | c.5326-1G>A p.X1776_splice | Splice Site (SNP) | VAF 15/36 reads (42%) | catalogued as COSV63762032; called by muse, mutect2
- DNAI3 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV54003245; called by muse, mutect2, varscan2
- DOCK11 | c.2926T>A p.L976M | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV52240633; called by muse, mutect2, varscan2
- DPYSL3 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 62/87 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV58327464; called by muse, mutect2, varscan2
- DSCAM | c.5400C>A p.S1800R | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68028541; called by muse, mutect2, varscan2
- DUOX1 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV50993814; called by muse, mutect2, varscan2
- EPHA8 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV51272201, COSV99384553; called by muse, mutect2, varscan2
- EXOSC4 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV60155914; called by muse, mutect2, varscan2
- FAM47A | c.1114G>T p.G372W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV60497497; called by muse, mutect2, varscan2
- FANCC | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.592); catalogued as COSV56661593; called by muse, mutect2, varscan2
- FLYWCH1 | c.1688G>T p.R563L (on ENST00000253928 / NM_001308068.2; = p.R562L on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs780119016, COSV54146729, COSV99558613; called by muse, mutect2
- FSD1 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55696534, COSV99697040; called by muse, mutect2, varscan2
- GFM1 | c.897C>A p.S299R | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51833240; called by muse, mutect2, varscan2
- GLA | c.508del p.D170Mfs*22 | Frame Shift Del (DEL) | VAF 43/216 reads (20%) | catalogued as CM032250, CM138854; called by mutect2, pindel, varscan2
- GLS | c.1372A>T p.S458C | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57842736; called by muse, mutect2, varscan2
- GNAT1 | c.560T>G p.F187C | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV50030466; called by muse, mutect2, varscan2
- GPR149 | c.638C>G p.T213S | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV67667779; called by muse, mutect2, varscan2
- GRIN3A | c.1366A>G p.I456V | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV62454759; called by muse, mutect2, varscan2
- HELZ | c.2818G>T p.V940L | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as COSV62378921; called by muse, mutect2, varscan2
- HID1 | c.1008G>A p.E336= | Splice Region (SNP) | VAF 116/231 reads (50%) | catalogued as COSV59351667; called by muse, mutect2, varscan2
- HMG20A | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1392475263, COSV60312883, COSV60313111; called by muse, mutect2, varscan2
- HSPA4L | c.985+1G>T p.X329_splice | Splice Site (SNP) | VAF 21/100 reads (21%) | catalogued as COSV56546066; called by muse, mutect2, varscan2
- HUWE1 | c.6777G>C p.Q2259H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV53348731; called by muse, mutect2, varscan2
- IGFN1 | c.3560A>G p.H1187R (on ENST00000295591 / NM_001367841.1; = p.H3644R on NM_001164586.2) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as rs755915827, COSV55174568; called by muse, mutect2, varscan2
- IGSF3 | c.2108T>A p.V703D (on ENST00000369486 / NM_001007237.3; = p.V723D on NM_001542.4) | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59592154; called by muse, mutect2, varscan2
- ISG20 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs769145683, COSV60143940; called by muse, mutect2, varscan2
- ITIH6 | c.3328C>A p.Q1110K | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54490034; called by muse, mutect2, varscan2
- KCNF1 | c.743T>A p.L248Q | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as COSV54463856; called by muse, mutect2, varscan2
- KCNQ1 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as COSV50107932, COSV50112285; called by muse, mutect2, varscan2
- KCNT1 | c.3542C>A p.P1181H (on ENST00000488444; = p.P1186H on NM_020822.3) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV53703189; called by muse, mutect2, varscan2
- LAMA1 | c.9064C>G p.P3022A | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67538680; called by muse, mutect2, varscan2
- LAMA2 | c.2663T>C p.I888T | Missense Mutation (SNP) | VAF 97/332 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.613); catalogued as rs1469533347, COSV70349799; called by muse, mutect2, varscan2
- LAMA2 | c.8900A>C p.E2967A | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV70349804; called by muse, mutect2
- LRFN5 | c.2072C>A p.T691K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as rs369488450, COSV53254589, COSV53260302; called by muse, mutect2, varscan2
- LRP1B | c.5500G>T p.G1834C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67231344; called by muse, mutect2, varscan2
- LRRC4C | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV53428026; called by muse, mutect2, varscan2
- LZTS2 | c.1457G>C p.R486P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs774166497, COSV64651818; called by muse, mutect2, varscan2
- MAN2C1 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1450304505, COSV51230352; called by muse, mutect2, varscan2
- MED14 | c.4291+2T>A p.X1431_splice | Splice Site (SNP) | VAF 16/95 reads (17%) | catalogued as COSV61357124; called by muse, mutect2, varscan2
- METTL7B | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as COSV57696285; called by muse, varscan2
- MOSPD2 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.097); catalogued as COSV66860256; called by muse, mutect2, varscan2
- MRC2 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100315809, COSV57640639; called by muse, mutect2, varscan2
- MUC16 | c.23438C>T p.P7813L | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); catalogued as COSV67472343; called by muse, mutect2, varscan2
- MYO7A | c.2971G>T p.E991* | Nonsense Mutation (SNP) | VAF 20/150 reads (13%) | catalogued as COSV68685054, COSV68685812; called by muse, mutect2, varscan2
- MYOM1 | c.55A>G p.N19D | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV55293405; called by muse, mutect2, varscan2
- NCAM1 | c.1795G>T p.A599S (on ENST00000316851 / NM_181351.5; = p.A589S on NM_000615.7) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV57510769, COSV57525977; called by muse, mutect2, varscan2
- NCKAP5 | c.5056G>C p.E1686Q | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV58449411; called by muse, mutect2
- NCOA2 | c.1023G>T p.L341F | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101475957; called by muse, mutect2, varscan2
- NPAT | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV53718651; called by muse, mutect2
- NRK | c.1400C>G p.A467G | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV54598560; called by muse, mutect2, varscan2
- NRK | c.3085G>T p.G1029* | Nonsense Mutation (SNP) | VAF 29/56 reads (52%) | catalogued as COSV54598577; called by muse, mutect2, varscan2
- NSMAF | c.2087T>C p.V696A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV50689041; called by muse, mutect2, varscan2
- NUTM1 | c.3099G>C p.R1033S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.154); catalogued as COSV59217228, COSV59218096; called by muse, mutect2, varscan2
- OPN5 | c.632C>A p.P211Q | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55245892; called by muse, mutect2, varscan2
- OPRM1 | c.171C>G p.S57R | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57678712; called by muse, mutect2, varscan2
- OR4C6 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV58604443; called by muse, mutect2, varscan2
- OR4C6 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.075); catalogued as COSV58604455; called by muse, mutect2, varscan2
- OR4D2 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV73459784; called by muse, mutect2, varscan2
- OR4N5 | c.198G>T p.L66F | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61320758; called by muse, mutect2
- OR51B5 | c.287T>C p.F96S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV56176283; called by muse, mutect2
- OR51I1 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV66508190; called by muse, mutect2, varscan2
- OR56B1 | c.512T>A p.L171H | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57723265, COSV57724155; called by muse, mutect2, varscan2
- P4HTM | c.1364A>G p.N455S (on ENST00000383729 / NM_177939.3; = p.N516S on NM_177938.2) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV59087487; called by muse, mutect2, varscan2
- PACRG | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762433151, COSV61306979; called by muse, mutect2, varscan2
- PACRGL | c.609+1G>T p.X203_splice | Splice Site (SNP) | VAF 20/66 reads (30%) | catalogued as COSV54843080; called by muse, mutect2, varscan2
- PALMD | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs760070084, COSV54165028; called by muse, mutect2, varscan2
- PAM | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV57214333; called by muse, mutect2, varscan2
- PAPPA2 | c.5003A>T p.E1668V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV62799807; called by muse, mutect2, varscan2
- PARP2 | c.1228G>C p.D410H | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV51639728; called by muse, mutect2
- PDK3 | c.728A>G p.H243R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV64793603, COSV64793887; called by muse, mutect2, varscan2
- PEDS1 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59012832; called by muse, mutect2
- PES1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs746766101, COSV100073116; called by muse, mutect2, varscan2
- PHKA2 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66054428; called by muse, mutect2, varscan2
- PHRF1 | c.3053G>T p.R1018L (on ENST00000264555 / NM_001286581.2; = p.R1017L on NM_020901.4) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs1246828429, COSV52757039; called by muse, mutect2, varscan2
- PIK3C2A | c.2143C>G p.H715D | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs1305079587, COSV56403736; called by muse, mutect2, varscan2
- PKD1L2 | c.2518C>G p.L840V | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV55163309; called by muse, mutect2, varscan2
- PLB1 | c.933G>T p.R311S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV59827555; called by muse, mutect2, varscan2
- PLEKHO2 | c.1463G>T p.S488I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60262246; called by muse, mutect2, varscan2
- PLSCR2 | c.479T>A p.V160D (on ENST00000497985 / NM_001199978.1; = p.V87D on NM_020359.2) | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60861807; called by muse, mutect2, varscan2
- POLA1 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771556456, COSV66884935; called by muse, mutect2, varscan2
- PRC1 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV62694805, COSV62695612; called by muse, mutect2, varscan2
- PREX2 | c.4310C>T p.S1437L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV55776384; called by muse, mutect2, varscan2
- PTCHD3 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV71256952; called by muse, mutect2, varscan2
- PTPRU | c.1869-2A>T p.X623_splice | Splice Site (SNP) | VAF 9/49 reads (18%) | catalogued as COSV60529553; called by muse, mutect2, varscan2
- PXDNL | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV62478104, COSV62493633; called by muse, mutect2, varscan2
- PYHIN1 | c.1453A>T p.T485S | Missense Mutation (SNP) | VAF 39/128 reads (30%) | PolyPhen benign (0.027); catalogued as COSV63731196; called by muse, mutect2, varscan2
- RLIM | c.604G>T p.V202F | Missense Mutation (SNP) | VAF 62/421 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs1355619416, COSV60327093; called by muse, mutect2, varscan2
- RPIA | c.33C>G p.Y11* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as COSV52170044; called by muse, mutect2, varscan2
- RSBN1 | c.1589T>C p.M530T | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV54732763; called by muse, mutect2, varscan2
- RTP1 | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56618702; called by muse, mutect2
- SCRIB | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); catalogued as CM125339, COSV57588270; called by muse, mutect2, varscan2
- SDK1 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV67372669; called by muse, mutect2, varscan2
- SERPINB6 | c.484G>T p.E162* (on ENST00000612421 / NM_001271823.2; = p.E143* on NM_004568.6) | Nonsense Mutation (SNP) | VAF 8/97 reads (8%) | catalogued as COSV59566106; called by muse, mutect2
- SHROOM3 | c.4394G>T p.S1465I | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56031205; called by muse, mutect2
- SLC14A1 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV58932668; called by muse, mutect2, varscan2
- SLC24A5 | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.224); catalogued as COSV58317865; called by muse, mutect2, varscan2
- SLFN13 | c.2602A>T p.I868F | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV53193933; called by muse, mutect2, varscan2
- SMARCAL1 | c.1233G>C p.K411N | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV61921538; called by muse, mutect2, varscan2
- SNAP47 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV59918263; called by muse, mutect2, varscan2
- SNX12 | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV52145765; called by muse, mutect2
- SP100 | c.862T>C p.S288P | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV50982649; called by muse, mutect2, varscan2
- SPATA2 | c.312G>T p.W104C | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV56866908; called by muse, mutect2, varscan2
- SUSD1 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs370355977; called by muse, mutect2, varscan2
- TAF4B | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs750922551, COSV52305117; called by muse, mutect2, varscan2
- TDRD10 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs370275136; called by muse, mutect2, varscan2
- TECRL | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV67087673; called by muse, mutect2, varscan2
- TEX13A | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV61161945; called by muse, mutect2, varscan2
- TIGD3 | c.538T>A p.L180M | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs763789448, COSV52889728; called by muse, mutect2, varscan2
- TKTL2 | c.1150G>T p.G384C | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV54919447; called by muse, mutect2, varscan2
- TKTL2 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV54919458; called by muse, mutect2, varscan2
- TLN2 | c.5883G>T p.K1961N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1184935282, COSV60890742; called by muse, mutect2
- TM9SF2 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV64506867; called by muse, mutect2, varscan2
- TMEM131L | c.2621C>T p.T874M | Missense Mutation (SNP) | VAF 15/263 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs1338694825, COSV53645576; called by muse, mutect2
- TMEM161B | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV56931402; called by muse, mutect2
- TPPP2 | c.470G>C p.S157T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs1472743463, COSV58794954; called by muse, mutect2, varscan2
- TRIM16L | c.969G>C p.K323N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV67459462; called by muse, mutect2, varscan2
- TRO | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV51502605; called by muse, mutect2, varscan2
- TRPA1 | c.2978G>C p.W993S | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV51563874, COSV51569055; called by muse, mutect2, varscan2
- TSSK2 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV52817251; called by muse, mutect2
- TTN | c.37707G>T p.Q12569H (on ENST00000591111; = p.Q5145H on NM_003319.4) | Missense Mutation (SNP) | VAF 93/326 reads (29%) | PolyPhen possibly damaging (0.874); catalogued as COSV100610189; called by muse, mutect2, varscan2
- TTN | c.18188T>C p.L6063S (on ENST00000591111; = p.L5136S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | PolyPhen benign (0.173); catalogued as COSV60118091; called by muse, mutect2, varscan2
- TTN | c.8217G>C p.Q2739H (on ENST00000591111; = p.Q2693H on NM_003319.4) | Missense Mutation (SNP) | VAF 42/141 reads (30%) | PolyPhen possibly damaging (0.855); catalogued as COSV60118120, COSV60218067; called by muse, mutect2, varscan2
- TUBGCP4 | c.1576G>C p.D526H (on ENST00000260383 / NM_001286414.3; = p.D525H on NM_014444.5) | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53019598; called by muse, mutect2, varscan2
- UBE2A | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV60636783, COSV60637132; called by muse, mutect2, varscan2
- UGGT2 | c.3685G>T p.D1229Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV65075569; called by muse, mutect2, varscan2
- UNC13C | c.4619T>C p.M1540T | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1374980736, COSV52883020, COSV99520244; called by muse, mutect2, varscan2
- USH2A | c.2667G>C p.L889F | Missense Mutation (SNP) | VAF 105/261 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56348251, COSV56382247; called by muse, mutect2, varscan2
- VWF | c.1478G>C p.S493T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.109); catalogued as COSV54623185, COSV54623699; called by muse, mutect2, varscan2
- WDR27 | c.510A>C p.K170N | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV61210132; called by muse, mutect2, varscan2
- ZFHX4 | c.5681C>A p.S1894Y | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV50999512, COSV99070792; called by muse, mutect2, varscan2
- ZFHX4 | c.6779C>A p.S2260Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51002342; called by muse, varscan2
- ZMYM3 | c.1286A>C p.H429P | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58738400; called by muse, mutect2
- ZNF185 | c.1513A>T p.T505S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV59276427; called by muse, mutect2, varscan2
- ZNF232 | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 120/186 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100005650; called by muse, mutect2, varscan2
- ZNF429 | c.1544G>A p.G515D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV61916658; called by muse, mutect2, varscan2
- ZNF431 | c.896G>C p.R299P | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV100218500, COSV60673564; called by muse, mutect2, varscan2
- ZNF479 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.737); catalogued as rs752204182, COSV58639472; called by muse, mutect2, varscan2
- ZNF513 | c.1398C>A p.H466Q | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52008288; called by muse, mutect2, varscan2
- ZNF714 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV52512494; called by muse, mutect2, varscan2
- ZNF714 | c.1508A>G p.Q503R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV52512514; called by muse, mutect2, varscan2
- ARFGEF1 | c.765_779del p.D255_Q259del | In Frame Del (DEL) | VAF 41/151 reads (27%) | called by mutect2, pindel, varscan2
- ASPN | c.1087_1094del p.T363Lfs*22 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- IGHG3 | c.861G>C p.E287D | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- IGSF9B | c.1260del p.Y421Ifs*37 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- INCENP | c.1235_1247del p.T412Sfs*42 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | called by mutect2, pindel
- KMT2D | c.4049_4056del p.K1350Rfs*5 | Frame Shift Del (DEL) | VAF 64/256 reads (25%) | called by mutect2, pindel, varscan2
- MAGEE2 | c.1533del p.K511Nfs*16 | Frame Shift Del (DEL) | VAF 61/193 reads (32%) | called by mutect2, pindel, varscan2
- MAP3K14 | c.1899del p.L634* | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- NOMO1 | c.1291_1312del p.V431Rfs*29 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, varscan2
- NRP1 | c.1978_1986delinsCATGTCA p.F660Hfs*6 | Frame Shift Del (DEL) | VAF 56/284 reads (20%) | called by pindel, varscan2*
- PCARE | c.1710del p.R571Gfs*11 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- SIN3B | c.317_338del p.L106Pfs*6 | Frame Shift Del (DEL) | VAF 54/231 reads (23%) | called by mutect2, pindel
- UBE2NL | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WASHC5 | c.3166_3169del p.Y1056Tfs*28 | Frame Shift Del (DEL) | VAF 33/111 reads (30%) | called by mutect2, pindel, varscan2
- ZNF569 | c.253_264del p.V85_H88del | In Frame Del (DEL) | VAF 10/77 reads (13%) | called by mutect2, pindel, varscan2
- ABCC11 | c.756A>T p.V252= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV62323731, COSV62325940; called by muse, mutect2, varscan2
- ACACA | c.5754C>A p.T1918= | Silent (SNP) | VAF 60/153 reads (39%) | called by muse, mutect2, varscan2
- ACRBP | c.150G>A p.L50= | Silent (SNP) | VAF 62/158 reads (39%) | catalogued as rs1434575640, COSV57524223, COSV99976287; called by muse, mutect2, varscan2
- ADAMTS18 | c.3411C>A p.V1137= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV99272342; called by muse, mutect2, varscan2
- ADGRG4 | c.6498T>A p.S2166= | Silent (SNP) | VAF 51/211 reads (24%) | catalogued as COSV54958335; called by muse, mutect2, varscan2
- ADPRH | c.30G>T p.L10= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV63695157; called by muse, mutect2, varscan2
- AKAP13 | c.3291A>G p.L1097= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as rs934668020, COSV63460891; called by muse, mutect2, varscan2
- AMER3 | c.1152C>T p.D384= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs200882863, COSV58467148; called by muse, mutect2, varscan2
- ANO8 | c.2298C>A p.P766= | Silent (SNP) | VAF 54/187 reads (29%) | catalogued as COSV50180657; called by muse, mutect2, varscan2
- APOB | c.1419G>A p.Q473= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as COSV51938830; called by muse, mutect2, varscan2
- ARHGDIB | c.501G>T p.L167= | Silent (SNP) | VAF 50/258 reads (19%) | catalogued as COSV56763609; called by muse, mutect2, varscan2
- CCDC157 | c.696G>A p.Q232= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV57839925; called by muse, mutect2
- CELF5 | c.597C>T p.T199= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV53012288; called by muse, mutect2, varscan2
- DGKD | c.3198G>C p.P1066= (on ENST00000264057 / NM_152879.3; = p.P1022= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV51054163; called by muse, varscan2
- EVX2 | c.111C>A p.L37= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as rs1232307752, COSV57963748; called by muse, mutect2, varscan2
- FAM120A | c.3356A>G p.*1119= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV52906081; called by muse, mutect2, varscan2
- FAM47B | c.648C>A p.P216= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs771203821, COSV61452762; called by muse, mutect2, varscan2
- FBH1 | c.297C>T p.S99= (on ENST00000362091 / NM_178150.3; = p.S150= on NM_032807.4) | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV62982928; called by muse, mutect2, varscan2
- FBLN2 | c.2748G>A p.T916= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs760215216, COSV55485928; called by muse, mutect2, varscan2
- FBN1 | c.7419C>A p.G2473= | Silent (SNP) | VAF 6/134 reads (4%) | catalogued as COSV57319436; called by muse, mutect2
- GAL3ST4 | c.1119C>T p.F373= | Silent (SNP) | VAF 7/157 reads (4%) | catalogued as COSV57586689; called by muse, mutect2
- GHR | c.279A>G p.E93= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV50115377; called by muse, mutect2, varscan2
- GRIN2B | c.3213G>A p.G1071= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV74206270; called by muse, mutect2, varscan2
- GRIN2C | c.1359C>T p.C453= | Silent (SNP) | VAF 110/243 reads (45%) | catalogued as COSV53113618; called by muse, mutect2, varscan2
- H3C6 | c.150C>G p.R50= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as rs1429463402, COSV64519396, COSV64519641; called by muse, mutect2
- HS6ST2 | c.1557A>G p.K519= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as COSV63713712; called by muse, varscan2
- IRS4 | c.357G>T p.R119= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV64534226; called by muse, mutect2, varscan2
- ITGA7 | c.495G>A p.V165= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV57696294; called by muse, mutect2, varscan2
- JCAD | c.3177G>A p.Q1059= | Silent (SNP) | VAF 13/242 reads (5%) | catalogued as COSV64760077, COSV64760666, COSV64762017; called by muse, mutect2
- KRTAP10-9 | c.795C>A p.A265= | Silent (SNP) | VAF 58/180 reads (32%) | catalogued as COSV59966174; called by muse, mutect2, varscan2
- KRTAP13-3 | c.144G>T p.L48= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV61879419; called by muse, mutect2, varscan2
- MAGEC1 | c.2163C>A p.L721= | Silent (SNP) | VAF 70/319 reads (22%) | catalogued as COSV53574277; called by muse, mutect2, varscan2
- MRC2 | c.1746G>T p.T582= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV57640629, COSV57642957; called by muse, mutect2, varscan2
- MUC17 | c.13194G>T p.G4398= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV60291388; called by muse, mutect2, varscan2
- MYH3 | c.2475C>T p.V825= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as COSV56866085; called by muse, mutect2, varscan2
- NECAP2 | c.486C>T p.I162= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs751356272, COSV61433426; called by muse, mutect2, varscan2
- NLRP14 | c.2508T>C p.S836= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as COSV55067983; called by muse, mutect2, varscan2
- OR10W1 | c.360G>A p.P120= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs200368241; called by muse, mutect2, varscan2
- OR4C6 | c.201G>A p.L67= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as rs191322588, COSV58604436; called by muse, mutect2, varscan2
- OR52N4 | c.708G>A p.R236= | Silent (SNP) | VAF 73/196 reads (37%) | catalogued as COSV57891419; called by muse, mutect2, varscan2
- PDE1A | c.1128G>C p.L376= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as COSV59525436; called by muse, mutect2, varscan2
- PEX1 | c.987T>G p.T329= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV50400839; called by muse, mutect2, varscan2
- PPFIA3 | c.165A>G p.T55= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV61952311; called by muse, mutect2, varscan2
- RIMS1 | c.2910A>T p.P970= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs751514883, COSV53460392; called by muse, mutect2, varscan2
- RIT2 | c.318A>T p.S106= | Silent (SNP) | VAF 127/423 reads (30%) | catalogued as COSV56301542; called by muse, mutect2, varscan2
- SBF2 | c.3444A>G p.S1148= | Silent (SNP) | VAF 75/220 reads (34%) | catalogued as COSV56301171; called by muse, mutect2, varscan2
- SKIDA1 | c.1605G>A p.P535= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV71610924; called by muse, mutect2, varscan2
- ZFHX4 | c.6780C>A p.S2260= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV50830472, COSV51004703; called by muse, varscan2
- C3P1 | n.2539C>T | RNA (SNP) | VAF 43/176 reads (24%) | catalogued as rs762065919; called by muse, mutect2, varscan2
- DCHS2 | n.8532A>C | RNA (SNP) | VAF 73/212 reads (34%) | catalogued as COSV61773285; called by muse, mutect2, varscan2
- SSPOP | n.11899C>T | RNA (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100948022, COSV65131517; called by muse, mutect2, varscan2
- TTN | c.10361-5166C>T | Intron (SNP) | VAF 41/137 reads (30%) | catalogued as rs376396183, COSV60007588; called by muse, mutect2, varscan2
- UBTFL2 | n.562A>T | RNA (SNP) | VAF 8/62 reads (13%) | catalogued as rs1375158237; called by mutect2, varscan2
- ZMAT5 | c.-1C>G | 5'UTR (SNP) | VAF 61/110 reads (55%) | catalogued as COSV100722622; called by muse, mutect2, varscan2
